Somatic mutation profile of tumor specimen TCGA-55-8087-01A (aliquot TCGA-55-8087-01A-11D-2238-08) from TCGA case TCGA-55-8087, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.3 years (21,655 days).
Specimen TCGA-55-8087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f23b4acf-62d8-4d13-b9fd-af057efe30e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8087-10A (Blood Derived Normal), aliquot TCGA-55-8087-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a75e3445-1617-494d-ac38-71e781f0f1c7

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR5 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777024733, COSV99709954; called by muse, mutect2, varscan2
- CACNA1H | c.6459G>T p.Q2153H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99326539; called by muse, varscan2
- DIO2 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101375839; called by muse, mutect2
- DMD | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV100818741; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs753591380, COSV100668268; called by muse, mutect2, varscan2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- GLDN | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100117577; called by muse, mutect2, varscan2
- IGSF10 | c.7055G>A p.G2352E | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99177225; called by muse, mutect2, varscan2
- KBTBD7 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs760576261, COSV65266886; called by muse, mutect2, varscan2
- KEL | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 40/651 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.132); catalogued as rs777299023, COSV62335240; called by muse, mutect2
- LAMA5 | c.5397C>G p.F1799L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV99438802; called by muse, mutect2, varscan2
- LRP1B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67222488; called by muse, mutect2
- MTHFSD | c.247dup p.T83Nfs*15 (on ENST00000360900 / NM_001159377.2; = p.T82Nfs*15 on NM_022764.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs1266793672; called by mutect2, varscan2
- NFIA | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs771496016, COSV100963557; called by muse, mutect2, varscan2
- OR8B8 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV100044941; called by muse, mutect2
- PCDHA2 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100973528, COSV100973707; called by muse, mutect2
- PTDSS1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs1375356638, COSV61265904; called by muse, mutect2, varscan2
- RTEL1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1206278611, COSV58896760; called by mutect2, varscan2
- TTC25 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as rs782026883, COSV66369306; called by muse, mutect2
- TTYH1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1171665390, COSV100001867; called by muse, mutect2, varscan2
- ZNF622 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV100433024; called by muse, mutect2, varscan2
- MAP3K3 | c.1315del p.L439* | Frame Shift Del (DEL) | VAF 25/179 reads (14%) | called by mutect2, pindel, varscan2
- XPNPEP3 | c.648dup p.D217* | Frame Shift Ins (INS) | VAF 61/211 reads (29%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.6666G>A p.S2222= | Silent (SNP) | VAF 134/363 reads (37%) | catalogued as rs769427885, COSV58224850; called by muse, varscan2
- C11orf68 | c.675C>G p.L225= (on ENST00000530188; = p.L266= on NM_031450.4) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100437073; called by muse, mutect2, varscan2
- DAGLB | c.207C>T p.V69= | Silent (SNP) | VAF 79/192 reads (41%) | catalogued as COSV99765740; called by muse, mutect2, varscan2
- KLK10 | c.183C>T p.V61= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100010995; called by muse, mutect2, varscan2
- MEOX2 | c.552C>T p.N184= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV100012040; called by muse, mutect2, varscan2
- MET | c.126G>A p.Q42= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs1167851500, COSV100577102; called by muse, mutect2, varscan2
- OR2T3 | c.771C>T p.F257= | Silent (SNP) | VAF 19/700 reads (3%) | catalogued as rs1451157176, COSV62081928; called by muse, mutect2
- SUCO | chr1:172532732 G>T | 5'Flank (SNP) | VAF 12/73 reads (16%) | catalogued as COSV55262452, COSV99742333; called by muse, mutect2, varscan2
